TARGET case TARGET-20-D7-EC-mock1 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/e82d16bd-f075-44d6-88d7-b59ad6db872c

Biospecimens (1 sample)
- Sample TARGET-20-D7-EC-mock1-85: Sample type: Next Generation Cancer Model; Tissue type: Normal.
